Somatic mutation profile of tumor specimen 64b606d7-d40f-41ae-b220-a66324 (aliquot 64b606d7-d40f-41ae-b220-a66324_D6_1) from CPTAC case 11CO072, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB.
Specimen 64b606d7-d40f-41ae-b220-a66324: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 325b5a83-ee37-4e3a-a475-89679a90b666.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0a628b4d-6b65-4105-812b-698836 (Blood Derived Normal), aliquot 0a628b4d-6b65-4105-812b-698836_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dfacfd93-3819-4182-a5eb-f7af9a830126

The open-access MAF lists 154 somatic variants for this specimen: 97 protein-altering or splice-affecting, 36 silent, 21 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 74, Silent 36, Nonsense Mutation 9, Intron 8, Frame Shift Ins 5, 5'UTR 4, 3'UTR 4, Frame Shift Del 3, RNA 3, In Frame Del 3, Splice Region 2, 5'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL2A1 | c.2219dup p.G741Wfs*29 | Frame Shift Ins (INS) | VAF 36/135 reads (27%) | catalogued as rs1565677720; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- NF1 | c.3721C>T p.R1241* | Nonsense Mutation (SNP) | VAF 118/274 reads (43%) | hotspot (GDC flag); catalogued as rs137854562, CM000799, COSV62191467; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 49/217 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs397507511, CM030493, COSV61004768, COSV61009351; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACP7 | c.1301G>A p.R434Q | Missense Mutation (SNP) | VAF 30/128 reads (23%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.543); catalogued as rs377306259; called by muse, mutect2, varscan2
- APC | c.4987G>A p.E1663K | Missense Mutation (SNP) | VAF 64/231 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.137); catalogued as rs758987855, COSV57337263, COSV99072973; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BAIAP3 | c.1081G>A p.V361I | Missense Mutation (SNP) | VAF 49/196 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.009); catalogued as rs1406317158; called by muse, mutect2, varscan2
- CFAP221 | c.1321G>T p.E441* | Nonsense Mutation (SNP) | VAF 35/95 reads (37%) | catalogued as COSV54655755; called by muse, mutect2, varscan2
- CHERP | c.1579C>T p.P527S | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.994); catalogued as rs972616637; called by mutect2, varscan2
- COL12A1 | c.9007C>G p.P3003A | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.031); catalogued as COSV100485104; called by muse, mutect2, varscan2
- COL2A1 | c.3929C>A p.A1310D | Missense Mutation (SNP) | VAF 71/222 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61530229; called by muse, mutect2, varscan2
- COL3A1 | c.3101G>A p.R1034H | Missense Mutation (SNP) | VAF 187/647 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs780788248, COSV58585041; called by muse, mutect2, varscan2
- COL4A5 | c.2952G>T p.Q984H | Missense Mutation (SNP) | VAF 95/329 reads (29%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.766); catalogued as COSV100088755; called by muse, mutect2, varscan2
- CPSF6 | c.1611_1622del p.D537_R540del | In Frame Del (DEL) | VAF 39/135 reads (29%) | catalogued as rs776381672; called by mutect2, varscan2
- DNAH17 | c.5581G>A p.G1861S | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1372365434; called by muse, mutect2, varscan2
- DRD3 | c.1172G>A p.R391Q | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746592271, COSV55680182; called by muse, mutect2, varscan2
- DTX3 | c.652C>T p.R218W | Missense Mutation (SNP) | VAF 66/219 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as rs745554527, COSV54085489; called by muse, mutect2, varscan2
- EPX | c.181C>T p.R61W | Missense Mutation (SNP) | VAF 79/281 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.8); catalogued as rs754444904, COSV56598362; called by muse, mutect2, varscan2
- ERCC2 | c.496C>T p.R166C | Missense Mutation (SNP) | VAF 71/269 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.849); catalogued as rs1032384332, COSV55544698; called by muse, mutect2, varscan2
- F7 | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 214/451 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV60645884; called by muse, mutect2, varscan2
- FAM161A | c.709A>G p.T237A | Missense Mutation (SNP) | VAF 86/261 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100281587; called by muse, mutect2, varscan2
- FHAD1 | c.3446G>A p.R1149H | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs770643908, COSV58990308; called by muse, mutect2, varscan2
- GPR161 | c.1475G>A p.R492Q | Missense Mutation (SNP) | VAF 88/269 reads (33%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.009); catalogued as rs1001678771, COSV54790146; called by muse, mutect2, varscan2
- HAP1 | c.1987C>T p.R663W (on ENST00000310778 / NM_001367460.1; = p.R611W on NM_177977.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 70/200 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs200875679; called by muse, mutect2, varscan2
- IQCF6 | c.181C>T p.R61W | Missense Mutation (SNP) | VAF 99/317 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV67241567; called by muse, mutect2, varscan2
- ITK | c.145C>T p.R49C | Missense Mutation (SNP) | VAF 86/270 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); catalogued as rs376961787; called by muse, mutect2, varscan2
- KIR2DL4 | c.527G>A p.R176H (on ENST00000396284; = p.R137H on NM_001080770.2) | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs537400112, COSV60877656; called by muse, varscan2
- KLF5 | c.911C>T p.P304L | Missense Mutation (SNP) | VAF 83/391 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs867921927, COSV66614545, COSV66614659; called by muse, mutect2, varscan2
- MFN2 | c.820C>T p.R274W | Missense Mutation (SNP) | VAF 88/196 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs762440627, CM1513317; called by muse, mutect2, varscan2
- MMP1 | c.871C>T p.R291W | Missense Mutation (SNP) | VAF 79/191 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200225512, COSV59510028, COSV59510961; called by muse, mutect2, varscan2
- MX2 | c.1345C>T p.R449C | Missense Mutation (SNP) | VAF 86/276 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1329272567; called by muse, mutect2, varscan2
- NAA35 | c.2032C>A p.H678N | Missense Mutation (SNP) | VAF 65/185 reads (35%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs749574848; called by muse, mutect2, varscan2
- NONO | c.1042C>T p.R348C | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs1298308316; called by muse, mutect2, varscan2
- PCDH11X | c.1457C>T p.T486M | Missense Mutation (SNP) | VAF 186/657 reads (28%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as rs62621113, COSV53445288, COSV53466454; called by muse, mutect2, varscan2
- PCDHA9 | c.1493G>A p.R498Q | Missense Mutation (SNP) | VAF 137/530 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.15); catalogued as rs536180374; called by muse, mutect2, varscan2
- PHACTR3 | c.970G>C p.D324H | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV63035770; called by muse, mutect2, varscan2
- PKHD1 | c.7285G>A p.V2429I | Missense Mutation (SNP) | VAF 144/519 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs148284341; called by muse, mutect2, varscan2
- PLCB1 | c.290G>A p.R97H | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT tolerated (0.63); PolyPhen benign (0.346); catalogued as rs747785129, COSV62054757, COSV99059820; called by muse, mutect2, varscan2
- PTEN | c.335T>G p.L112R | Missense Mutation (SNP) | VAF 175/401 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM981669, COSV64294101, COSV64304040; called by muse, mutect2, varscan2
- RBMXL2 | c.17G>A p.R6H | Missense Mutation (SNP) | VAF 134/488 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.081); catalogued as rs774735787, COSV100182082; called by muse, mutect2, varscan2
- RXFP3 | c.934C>T p.R312C | Missense Mutation (SNP) | VAF 112/431 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as COSV57504831; called by muse, mutect2, varscan2
- RYR1 | c.5482G>A p.D1828N | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs866052916, COSV62111533; called by muse, mutect2
- SVIL | c.1994G>T p.R665L | Missense Mutation (SNP) | VAF 71/152 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV100881623; called by muse, mutect2, varscan2
- THSD7B | c.914C>T p.S305L | Missense Mutation (SNP) | VAF 41/168 reads (24%) | SIFT tolerated (0.66); PolyPhen benign (0.025); catalogued as rs866588841, COSV55651332; called by muse, mutect2, varscan2
- TP53I11 | c.550C>T p.R184* | Nonsense Mutation (SNP) | VAF 57/196 reads (29%) | catalogued as rs764297864; called by muse, mutect2, varscan2
- ZFHX4 | c.1096G>A p.A366T | Missense Mutation (SNP) | VAF 127/512 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.043); catalogued as rs1317244615, COSV50765162; called by muse, mutect2, varscan2
- ZSWIM3 | c.2011G>A p.V671M | Missense Mutation (SNP) | VAF 155/236 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as rs750733599, COSV99666384; called by muse, mutect2, varscan2
- ADCY1 | c.2413G>A p.V805M | Missense Mutation (SNP) | VAF 36/152 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- ANGPTL6 | c.772C>T p.Q258* | Nonsense Mutation (SNP) | VAF 15/39 reads (38%) | called by muse, mutect2, varscan2
- ANKRD28 | c.2242A>C p.N748H | Missense Mutation (SNP) | VAF 58/187 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AOC2 | c.89G>C p.G30A | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AP1G1 | c.1636_1639del p.K546Wfs*18 | Frame Shift Del (DEL) | VAF 26/89 reads (29%) | called by mutect2, pindel, varscan2
- APC | c.2176_2177del p.L726Kfs*7 | Frame Shift Del (DEL) | VAF 80/344 reads (23%) | called by mutect2, pindel, varscan2
- APC | c.4462_4463insAT p.L1488Yfs*20 | Frame Shift Ins (INS) | VAF 58/274 reads (21%) | called by mutect2, pindel, varscan2
- ARHGAP15 | c.1094C>T p.P365L | Missense Mutation (SNP) | VAF 51/219 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGAP6 | c.293C>G p.P98R | Missense Mutation (SNP) | VAF 61/204 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- CALML4 | c.7G>T p.A3S | Missense Mutation (SNP) | VAF 7/136 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2
- CANX | c.1248G>A p.M416I | Missense Mutation (SNP) | VAF 68/255 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- CCDC74A | c.331G>T p.A111S | Missense Mutation (SNP) | VAF 88/335 reads (26%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- CFAP53 | c.1327T>G p.L443V | Missense Mutation (SNP) | VAF 52/134 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- DALRD3 | c.462G>T p.G154= | Splice Region (SNP) | VAF 42/167 reads (25%) | called by muse, mutect2, varscan2
- DCLK1 | c.1964_1965insC p.E656* | Frame Shift Ins (INS) | VAF 35/114 reads (31%) | called by mutect2, pindel, varscan2
- DISP1 | c.2113T>A p.F705I | Missense Mutation (SNP) | VAF 86/517 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.374); called by mutect2, varscan2
- DYNLT3 | c.166G>T p.V56F | Missense Mutation (SNP) | VAF 40/125 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- ETV1 | c.802G>T p.E268* | Nonsense Mutation (SNP) | VAF 9/160 reads (6%) | called by muse, mutect2
- FEM1C | c.658_659del p.A221Kfs*25 | Frame Shift Del (DEL) | VAF 64/258 reads (25%) | called by pindel, varscan2
- FGD1 | c.698G>T p.G233V | Missense Mutation (SNP) | VAF 45/155 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- GNAS | c.1415_1432del p.E472_P477del | In Frame Del (DEL) | VAF 40/168 reads (24%) | called by mutect2, varscan2
- GOLGB1 | c.181G>T p.V61L | Missense Mutation (SNP) | VAF 45/182 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- GPR25 | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- HSPBAP1 | c.1358C>G p.T453S | Missense Mutation (SNP) | VAF 92/307 reads (30%) | SIFT tolerated (0.9); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KCNRG | c.480G>C p.Q160H | Missense Mutation (SNP) | VAF 61/208 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- KIAA0825 | c.3710+2T>A p.X1237_splice | Splice Site (SNP) | VAF 31/82 reads (38%) | called by muse, mutect2, varscan2
- LAMA2 | c.691G>T p.E231* | Nonsense Mutation (SNP) | VAF 94/336 reads (28%) | called by muse, mutect2, varscan2
- MRGPRD | c.551C>T p.A184V | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT tolerated (0.87); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NHS | c.994A>T p.K332* | Nonsense Mutation (SNP) | VAF 47/171 reads (27%) | called by muse, mutect2, varscan2
- NIM1K | c.1176T>G p.H392Q | Missense Mutation (SNP) | VAF 108/325 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- OSBPL8 | c.1351G>C p.E451Q | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT tolerated (0.58); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- PACC1 | c.946G>C p.A316P | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); called by muse, mutect2
- PAPPA2 | c.766T>C p.S256P | Missense Mutation (SNP) | VAF 94/363 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDHB14 | c.1829C>T p.T610M | Missense Mutation (SNP) | VAF 188/627 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- PRMT1 | c.25dup p.C9Lfs*12 | Frame Shift Ins (INS) | VAF 4/16 reads (25%) | called by mutect2, varscan2
- PTER | c.720G>C p.E240D | Missense Mutation (SNP) | VAF 76/222 reads (34%) | SIFT tolerated (0.62); PolyPhen benign (0.003); called by muse, mutect2
- RGS13 | c.1dup | Splice Region (INS) | VAF 30/111 reads (27%) | called by mutect2, pindel, varscan2
- ROBO1 | c.679A>G p.I227V | Missense Mutation (SNP) | VAF 36/169 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- SAFB2 | c.1738G>C p.E580Q | Missense Mutation (SNP) | VAF 29/193 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SLC26A5 | c.1648G>T p.D550Y | Missense Mutation (SNP) | VAF 95/271 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SMCHD1 | c.470C>T p.S157F | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- STYXL2 | c.613A>T p.K205* | Nonsense Mutation (SNP) | VAF 56/223 reads (25%) | called by muse, mutect2, varscan2
- SYVN1 | c.330_332del p.L111del | In Frame Del (DEL) | VAF 35/198 reads (18%) | called by pindel, varscan2
- TENM1 | c.7021C>A p.P2341T | Missense Mutation (SNP) | VAF 87/282 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- TEX47 | c.473T>C p.L158P | Missense Mutation (SNP) | VAF 77/320 reads (24%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UBR4 | c.13078G>C p.E4360Q | Missense Mutation (SNP) | VAF 58/138 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- VCP | c.1207A>T p.T403S | Missense Mutation (SNP) | VAF 118/367 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ZFP36L2 | c.478dup p.R160Pfs*314 | Frame Shift Ins (INS) | VAF 85/335 reads (25%) | called by mutect2, pindel, varscan2
- ZMYM4 | c.2543G>C p.C848S | Missense Mutation (SNP) | VAF 49/161 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- ZNF700 | c.760C>T p.Q254* | Nonsense Mutation (SNP) | VAF 35/136 reads (26%) | called by muse, mutect2, varscan2
- ZRANB3 | c.826G>C p.D276H | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- AHSP | c.93C>A p.L31= | Silent (SNP) | VAF 112/385 reads (29%) | catalogued as rs144049475; called by muse, mutect2, varscan2
- ATP8B4 | c.1173C>T p.S391= | Silent (SNP) | VAF 27/433 reads (6%) | catalogued as rs770476015, COSV52710285, COSV99464462; called by muse, mutect2
- C2orf42 | c.1407G>A p.E469= | Silent (SNP) | VAF 20/65 reads (31%) | called by muse, mutect2, varscan2
- COL11A2 | c.1734C>T p.A578= (on ENST00000341947 / NM_080680.3; = p.A471= on NM_080679.2) | Silent (SNP) | VAF 60/245 reads (24%) | catalogued as rs753897619; called by muse, mutect2, varscan2
- CSMD1 | c.9846G>A p.P3282= (on ENST00000520002; = p.P3281= on NM_033225.6) | Silent (SNP) | VAF 17/66 reads (26%) | catalogued as rs759034746, COSV59310803; called by muse, mutect2, varscan2
- DCAF4 | c.774G>T p.L258= | Silent (SNP) | VAF 25/64 reads (39%) | catalogued as COSV62319317; called by muse, mutect2, varscan2
- FBXL18 | c.675G>A p.P225= | Silent (SNP) | VAF 28/110 reads (25%) | catalogued as rs767700957, COSV66667757; called by muse, mutect2, varscan2
- FRMPD3 | c.948C>T p.I316= | Silent (SNP) | VAF 49/150 reads (33%) | called by muse, mutect2, varscan2
- HSP90AB1 | c.2076A>G p.E692= | Silent (SNP) | VAF 69/238 reads (29%) | called by muse, mutect2, varscan2
- HTR2C | c.462A>G p.V154= | Silent (SNP) | VAF 47/142 reads (33%) | called by muse, mutect2, varscan2
- IGF2R | c.4431C>T p.S1477= | Silent (SNP) | VAF 59/216 reads (27%) | catalogued as rs750302515, COSV63630880; called by muse, mutect2, varscan2
- IQSEC3 | c.1368G>A p.P456= (on ENST00000538872 / NM_001170738.2; = p.P153= on NM_015232.1) | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as rs782673474, COSV58289189; called by muse, mutect2, varscan2
- JAKMIP1 | c.366C>T p.D122= | Silent (SNP) | VAF 99/334 reads (30%) | catalogued as rs199613129; called by muse, mutect2, varscan2
- LYAR | c.318C>T p.N106= | Silent (SNP) | VAF 64/178 reads (36%) | catalogued as COSV58644175; called by muse, mutect2, varscan2
- MIER3 | c.456T>C p.G152= | Silent (SNP) | VAF 53/205 reads (26%) | called by muse, mutect2, varscan2
- MMP7 | c.798G>A p.K266= | Silent (SNP) | VAF 56/197 reads (28%) | called by muse, mutect2, varscan2
- MRGBP | c.315C>T p.F105= | Silent (SNP) | VAF 34/248 reads (14%) | catalogued as rs766780072; called by muse, mutect2, varscan2
- MYLK | c.2385G>A p.L795= | Silent (SNP) | VAF 96/384 reads (25%) | called by muse, mutect2, varscan2
- NELL1 | c.2002C>A p.R668= | Silent (SNP) | VAF 37/117 reads (32%) | catalogued as COSV54268570; called by muse, mutect2, varscan2
- PIM2 | c.150C>T p.H50= | Silent (SNP) | VAF 47/161 reads (29%) | called by muse, mutect2, varscan2
- PRR30 | c.558C>T p.S186= | Silent (SNP) | VAF 26/88 reads (30%) | catalogued as rs770356521, COSV53204331; called by muse, mutect2, varscan2
- PWWP3B | c.1926A>G p.P642= | Silent (SNP) | VAF 132/403 reads (33%) | called by muse, mutect2, varscan2
- RBCK1 | c.270G>T p.L90= (on ENST00000356286 / NM_031229.4; = p.L48= on NM_006462.6) | Silent (SNP) | VAF 18/134 reads (13%) | catalogued as COSV100675729; called by muse, mutect2, varscan2
- RPL13 | c.318C>G p.S106= | Silent (SNP) | VAF 70/242 reads (29%) | called by mutect2, varscan2
- RYR1 | c.5226C>T p.R1742= | Silent (SNP) | VAF 126/366 reads (34%) | catalogued as rs567818625, COSV62087715; ClinVar: likely benign; called by muse, mutect2, varscan2
- SHANK1 | c.5778C>T p.D1926= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as rs745571709; called by muse, mutect2, varscan2
- SIPA1 | c.159C>T p.S53= | Silent (SNP) | VAF 44/169 reads (26%) | catalogued as rs1302639744, COSV100855864; called by muse, mutect2, varscan2
- SLIT1 | c.912G>A p.P304= | Silent (SNP) | VAF 20/57 reads (35%) | catalogued as rs1227392043; called by muse, mutect2, varscan2
- SRC | c.1299T>G p.A433= | Silent (SNP) | VAF 32/155 reads (21%) | called by mutect2, varscan2
- SURF2 | c.129C>A p.L43= | Silent (SNP) | VAF 33/106 reads (31%) | called by muse, mutect2, varscan2
- TGFBI | c.693C>A p.L231= | Silent (SNP) | VAF 26/189 reads (14%) | called by muse, mutect2, varscan2
- TMPRSS13 | c.1440C>T p.C480= | Silent (SNP) | VAF 56/227 reads (25%) | called by muse, mutect2, varscan2
- TOP3A | c.2208C>T p.C736= | Silent (SNP) | VAF 4/28 reads (14%) | called by muse, mutect2
- TRPC4 | c.2820G>A p.T940= (on ENST00000379705 / NM_016179.4; = p.T945= on NM_003306.3) | Silent (SNP) | VAF 82/211 reads (39%) | catalogued as rs1426730736; called by muse, mutect2, varscan2
- UNC5A | c.537C>T p.A179= | Silent (SNP) | VAF 31/119 reads (26%) | catalogued as rs373056438; called by muse, mutect2, varscan2
- ZAN | c.5100C>T p.G1700= | Silent (SNP) | VAF 35/119 reads (29%) | catalogued as rs781312732, COSV61815382; called by muse, mutect2, varscan2
- AC136604.1 | n.637G>A | RNA (SNP) | VAF 100/338 reads (30%) | catalogued as rs371732819; called by muse, mutect2, varscan2
- ATXN10 | c.*25_*26insA | 3'UTR (INS) | VAF 55/174 reads (32%) | called by mutect2, pindel, varscan2
- C3orf84 | c.141+37A>G | Intron (SNP) | VAF 54/155 reads (35%) | called by muse, mutect2, varscan2
- C7orf26 | c.1149-346C>A | Intron (SNP) | VAF 20/82 reads (24%) | called by muse, mutect2, varscan2
- CDKL1 | c.293+953G>T | Intron (SNP) | VAF 27/72 reads (38%) | catalogued as COSV53581096; called by muse, mutect2, varscan2
- CLU | c.*904C>A | 3'UTR (SNP) | VAF 117/282 reads (41%) | catalogued as rs549395690; called by muse, mutect2, varscan2
- DPAGT1 | c.917+48G>A | Intron (SNP) | VAF 83/254 reads (33%) | called by muse, mutect2, varscan2
- ECRG4 | c.-12C>T | 5'UTR (SNP) | VAF 18/52 reads (35%) | called by muse, mutect2, varscan2
- EIF2B5 | c.507-5dup | Intron (INS) | VAF 140/458 reads (31%) | catalogued as rs765467600; called by mutect2, varscan2
- FMR1 | c.1737+47G>C | Intron (SNP) | VAF 61/216 reads (28%) | called by muse, mutect2, varscan2
- GTF2H2C | c.-29T>G | 5'UTR (SNP) | VAF 33/134 reads (25%) | called by muse, mutect2, varscan2
- MBNL1 | c.174+40171T>G | Intron (SNP) | VAF 32/104 reads (31%) | catalogued as rs763202551; called by muse, mutect2, varscan2
- MIR6511A4 | chr16:18347698 G>T | 5'Flank (SNP) | VAF 14/120 reads (12%) | called by mutect2, varscan2
- NEK6 | c.-21C>T | 5'UTR (SNP) | VAF 54/168 reads (32%) | called by muse, mutect2, varscan2
- POM121L8P | n.776G>A | RNA (SNP) | VAF 12/88 reads (14%) | catalogued as rs9608949; called by muse, varscan2
- TAAR3P | n.579C>A | RNA (SNP) | VAF 130/458 reads (28%) | called by muse, mutect2, varscan2
- THAP5 | c.-5G>T | 5'UTR (SNP) | VAF 51/172 reads (30%) | called by muse, mutect2, varscan2
- TRDV2 | chr14:22418692 G>A | 5'Flank (SNP) | VAF 60/136 reads (44%) | called by muse, mutect2, varscan2
- TSPAN9 | c.63+5075G>A | Intron (SNP) | VAF 42/152 reads (28%) | catalogued as rs751375191; called by muse, mutect2, varscan2
- ZKSCAN4 | c.*111del | 3'UTR (DEL) | VAF 55/210 reads (26%) | called by mutect2, pindel, varscan2
- ZNF487 | c.*1050G>C | 3'UTR (SNP) | VAF 90/240 reads (38%) | called by muse, mutect2, varscan2
